CCDI case PBCBUL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/fe588443-8e80-4401-b400-a7c81836d333

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.1 years (1,116 days).

Biospecimens (3 samples)
- Sample 0DNKZD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNKZI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DNKZN: Tissue type: Tumor; Specimen type: Solid Tissue.
